TCGA case TCGA-AR-A254 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6014a582-d22e-46e1-9000-c8e2fbad7acf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,270 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Inner / Breast, Left Lower Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 9; Lymph nodes tested: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 22 days; Days to treatment end: 43 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trastuzumab; Days to treatment start: 22 days; Days to treatment end: 22 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trastuzumab; Days to treatment start: 29 days; Days to treatment end: 184 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Days to treatment start: 50 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Epirubicin; Days to treatment start: 106 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 106 days; Days to treatment end: 173 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trastuzumab; Days to treatment start: 232 days; Days to treatment end: 344 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 252 days; Days to treatment end: 291 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Days to treatment start: 262 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (3 entries)
- Days to follow up: 2,213 days (6.1 years); Disease response: Tumor Free.
- Days to follow up: 2,605 days (7.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,212.

Molecular and laboratory tests
- ERBB2 (IHC): Positive; Staining intensity value: 3+.
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 990 mg.
  Slide TCGA-AR-A254-01A-02-TSB: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AR-A254-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A254-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; First surgical procedure other: Wide local excision; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Her2 IHC score: 3+; Margin status: Negative; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Wide local incision; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Inner Quadrant; Anatomic organ subdivision: Left Lower Inner Quadrant.
- Follow-up form 1: New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Abraxane.
- Drug treatment 5: Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,605 days; disease-specific survival: no event (censored), 2,605 days; disease-free interval: no event (censored), 2,605 days; progression-free interval: no event (censored), 2,605 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A254-01A-21D-A166-01): tumor purity 0.45, ploidy 3.38, whole-genome doublings 1.
